TCGA case TCGA-24-2260 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f2ce00e4-0d4f-4faa-bee1-ddf1b306e97b

Demographics
Sex at birth: female; Race: white; Age at index: 74 years; Vital status: Dead; Days to death: 1,100 days (3.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,112 days); Year of diagnosis: 1992; Method of diagnosis: Fine Needle Aspiration; FIGO stage: Stage IIIB; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 135 days; Number of cycles: 6; Treatment dose: 727 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 135 days; Number of cycles: 6; Treatment dose: 1,110 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 682 days (1.9 years); Days to treatment end: 849 days (2.3 years); Number of cycles: 7; Treatment dose: 2,905 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Recurrent Disease; Days to treatment start: 682 days (1.9 years); Days to treatment end: 849 days (2.3 years); Number of cycles: 7; Treatment dose: 5,810 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Altretamine; Initial disease status: Progressive Disease; Days to treatment start: 876 days (2.4 years); Days to treatment end: 1,009 days (2.8 years); Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Chlorambucil; Initial disease status: Progressive Disease; Days to treatment start: 1,011 days (2.8 years); Days to treatment end: 1,081 days (3.0 years); Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 76.1 years (27,779 days); Days to diagnosis: 667 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 667 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 667 days (1.8 years); Evidence of recurrence type: Physical Examination.
- Days to follow up: 1,100 days (3.0 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-24-2260-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-24-2260-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-24-2260-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Fine needle aspiration biopsy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Hexalen; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxol.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,100 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,100 days; disease-free interval: event (new tumor event after initially disease-free), 667 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 667 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2260-01A-01D-0663-01): tumor purity 0.84, ploidy 3.15, whole-genome doublings 1.
